Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4874, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4874-01A (Primary Tumor).

iology Report

DIAGNOSIS

(A) LEFT KIDNEY AND LYMPH NODE:

CONVENTIONAL RENAL CELL CARCINOMA, CLEAR CELL TYPE, FUHRMAN'S

NUCLEAR GRADE 3.

TUMOR MEASURES 6.0 CM IN MAXIMUM DIMENSION.

TUMOR CONFINED TO THE KIDNEY.

Margins of resection free of tumor.

Simple cortical cyst.

GROSS DESCRIPTION

(A) LEFT KIDNEY WITH EN BLOC LYMPH NODE - A radical nephrectomy specimen (19.5 x 10.0 x 5.0 cm) including left

kidney (12.5 x 6.0 x 4.0 cm), a segment of renal artery, renal vein and ureter (10.0 cm in length and 0.4 cm average diameter).

There is a 6.0 x 5.5 x 5.0 cm well-circumscribed tumor in the mid-lower pole of the kidney. The tumor is yellow with focal areas of hemorrhage and necrosis, which are present predominantly in the center of the tumor. The tumor is close to but does not appear to invade into the perinephric adipose tissue, renal sinus and renal vein. The tumor does not extend to Gerota's fascia.

There is one simple cyst (1.0 cm) present and it is 2.0 cm from the tumor in the kidney parenchyma. The pelvicaliceal system is smooth and devoid of any lesions. Seven unremarkable lymph nodes are grossly identified in the hilum of the kidney, they range in size from 0.5 x 1.0 cm.

A portion of the tumor has been submitted for possible electron microscopy, as well as other research protocols.

SECTION CODE: A1, ureter, renal vein and artery margins; A2-A7, tumor with perinephric fat; A8-A10, tumor with renal sinus; A11, simple cyst;

, representative section of the non-neoplastic kidney; A13, four lymph nodes; A14, one lymph node; A15, one lymph node bisected; A16, one lymph node bisected; A17, dilated part of ureter, en face; A18, narrow part of ureter, en face.

CLINICAL HISTORY

History of left renal mass.

SNOMED CODES

T-71000, M-63123

Source: NCI Genomic Data Commons file f8288d4d-28c6-44a0-ae6d-66d0694746b9 (TCGA-CJ-4874.FEBE6B82-1E08-4F8A-B024-59F50D68FF29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).